Gene-level copy-number profile of specimen HCM-CSHL-0094-C25-85B from HCMI case HCM-CSHL-0094-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.5 years (22,468 days).
Specimen HCM-CSHL-0094-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5022f7d6-c3e3-4a5c-8389-c45c7356832f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0094-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/7c9854fa-e642-4310-8101-09a3bd9c6f23

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2; copy number 2: 14,138; copy number 3: 32,096; copy number 4: 11,185; copy number 5: 657; copy number 6: 280; copy number 7: 26; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:167,965,187–168,187,719, 4 genes (within-gene range 0–2): AC008705.2, AC008705.1, AC011369.1, AC011369.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 27 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:38,906,451–38,996,882, 2 genes, copy number 7 (within-gene range 6–7): CPNE8-AS1, AC018448.2.
- chr12:54,575,387–54,648,493, 4 genes, copy number 7 (within-gene range 6–7): PPP1R1A, GLYCAM1, LACRT, DCD.
- chr12:55,342,841–55,343,774, 1 gene, copy number 7: OR6C7P.
- chr12:55,400,430–55,414,787, 2 genes, copy number 7: OR6C65, PHC1P1.
- chr12:56,822,985–57,132,139, 15 genes, copy number 7 (within-gene range 6–7): AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16, AC026120.1, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6.
- chr12:58,544,124–58,813,060, 2 genes, copy number 7: AC020637.1, LINC02388.
- chr12:126,524,248–126,524,626, 1 gene, copy number 10: NDUFA5P6.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
